Gene-level copy-number profile of tumor specimen TCGA-TN-A7HI-01A from TCGA case TCGA-TN-A7HI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 56.6 years (20,666 days).
Specimen TCGA-TN-A7HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.57e405be-d0e7-4bd8-9f3c-5f29100c8a59.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TN-A7HI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd9ea0d9-9cdd-4213-85f2-6e577fd80401

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11; copy number 2: 38,287; copy number 3: 12,713; copy number 4: 4,076; copy number 5: 1,460; copy number 6: 3,172; copy number 7: 82; copy number 8: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TN-A7HI-01A-11D-A34I-01): tumor purity 0.73, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,720 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:181,699,608–182,158,313, 12 genes, copy number 8: AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1.
- chr8:150,584–145,066,685, 2,481 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr9:14,475–28,670,286, 377 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:29,214,322–43,045,120, 396 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–16,053,197, 291 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
